Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A4S1, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A4S1-01A (Primary Tumor).

[page 1 of 5]
Name: [REDACTED] Age/Sex: F Location: [REDACTED]
Acct#: [REDACTED] Unit#: [REDACTED] Status: [REDACTED] Room/Bed: [REDACTED]
Reg: [REDACTED] Disch: [REDACTED] Att Dr: [REDACTED], M.D.

This report contains corrections, additions or deletions.
Any previous versions are stored internally and are available if necessary.

Specimen: Received: Status: Req#: [REDACTED]
Collected: Sp type: SURGICAL P
Subm Dr: [REDACTED], M.D.

PREOPERATIVE DIAGNOSIS

174-RT BREAST CANCER-INVASIVE

OPERATION PERFORMED

DATE:

DOCTOR(S):

PROCEDURE: MASTECTOMY PARTIAL LUMPECTOMY, ULTRASONIC NEEDLE LOC BREAST BX

PROCEDURE (CONT): BX SENTINEL NODE

TISSUE REMOVED

- A. RT PARTIAL MASTECTOMY POSSIBLE SARCOMA SHORT STITCH SUPERIOR MEDIAL SKIN MARGIN LONG STITCH LATERAL SKIN MARGIN @
- B. RT BREAST MEDIAL MARGIN AT
- C. RT BREAST SUPERIOR MARGIN @
- D. RT BREAST LATERAL MARGIN @
- E. RT BREAST INFERIOR MARGIN AT
- F. RT BREAST POSTERIOR MARGIN @
- G. RT BREAST ANTERIOR MARGIN @
- H. RT BREAST MEDIAL POSTERIOR MARGIN @
- I. RT AXILLARY SENTINEL NODE HOT AND BLUE COUNT 241 @

1ED-0-3
carcinoma, metaplastic, NOS
8575/3
Site: breast, NOS
c50.9
pw
10/26/12

GROSS DESCRIPTION

RECEIVED IN 9 PARTS.

A RECEIVED LABELED [REDACTED] RIGHT BREAST PARTIAL MASTECTOMY POSSIBLE SARCOMA SHORT SUPERIOR MEDIAL SKIN MARGIN LONG LATERAL SKIN MARGIN IS A 167 GRAMS PARTIAL MASTECTOMY WITH A 10 X 4.5 CM SKIN ELLIPSE. ON THE LATERAL PORTION OF THE SPECIMEN THERE ARE SEVERAL ELEVATED SLIGHTLY DARKENED SKIN LESIONS THE LARGEST 0.5 X 0.4 CM. ONE OF THESE IS GROSSLY FOUND TO BE A SUPERIOR LATERAL SKIN MARGIN. THERE IS A PROMINENT PALPABLE MASS WITHIN THE SPECIMEN. THE MARGINS ARE MARKED AS FOLLOWS USING SKIN AS THE ANTERIOR MARGIN: LATERAL ORANGE, MEDIAL RED, INFERIOR BLUE, SUPERIOR GREEN, POSTERIOR BLACK. RED-BROWN MUSCLE FIBERS ARE NOTED IN THE AREA OF THE MASS ON THE POSTERIOR ASPECT WHICH OTHERWISE HAS A SMOOTH APPEARANCE. SECTIONING REVEALS A DISCRETE

[page 2 of 5]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

GROSS DESCRIPTION

(Continued)

FIRM GRAY MASS MEASURING 3.4 X 2.8 X 2.8 CM. CENTRALLY THERE IS RED DISCOLORATION TO THE NODULE AND ANTERIOR INFERIORLY TO THIS THERE IS A 1.3 CM IN DIAMETER AREA OF RED-BROWN BLOOD. THE DEEP MEMBRANOUS SURFACE EASILY SLIDES OVER THIS MASS WHICH IS ONLY COVERED GROSSLY BY THE DEEP FASCIA AND MUSCLE FIBERS. IT IS OTHERWISE GREATER THAN 1 CM FROM ALL MARGINS. SECTIONS ARE SUBMITTED AS FOLLOWS: A1--REPRESENTATIVE PERPENDICULAR MEDIAL MARGIN, A2--REPRESENTATIVE PERPENDICULAR LATERAL MARGIN, A3 THROUGH A9--FULL CROSS SECTION OF THE LESION TO INCLUDE THE DEEP MARGIN (A3) AND THE ADJACENT HEMORRHAGIC AREA (A5), A6--OVERLYING SKIN TO THIS NODULE, AND REPRESENTATIVE SKIN LESION, A7--REPRESENTATIVE SUPERIOR MARGIN TO THIS LESION, A8 AND A9--REPRESENTATIVE INFERIOR MARGIN TO THIS LESION, A10--CROSS SECTION OF LESION TO INCLUDE POSTERIOR MARGIN, A11--THE HEMORRHAGIC AREA ADJACENT TO A10, A12--LATERAL PORTION OF LESION WITH ADJACENT HEMORRHAGIC TISSUE.

NOTE: RANDOM SECTIONS OF THE MASS ARE SUBMITTED PER PROTOCOL AS P1-P5 WITH MIRROR IMAGE SECTION FROZEN OF P1 AND P2 AS WELL AS RANDOM TISSUE FRESH FROZEN. A PORTION OF SKIN IS ALSO SUBMITTED AS P6 FROM THE AREA OF SKIN IN A6.

B RECEIVED LABELED [REDACTED] BREAST MEDIAL MARGIN IS A 5 X 3.9 X 1.2 CM FRAGMENT OF YELLOW FATTY TISSUE. PURPLE-BLUE COLORATION IS NOTED ON ONE SURFACE. THIS SURFACE IS REMARKED WITH BLUE INK WITH A PERIMETER OF BLACK. THIS IS SECTIONED AND SUBMITTED AS B1-B9.

C RECEIVED LABELED [REDACTED] RIGHT BREAST SUPERIOR MARGIN IS A 3.8 X 2.8 X 1.1 CM FRAGMENT OF YELLOW FATTY TISSUE. BLUE COLORATION IS SEEN ON ONE SIDE OF THE SPECIMEN. THIS SIDE IS REMARKED WITH BLUE INK WITH A PERIMETER OF BLACK. THIS IS SECTIONED AND SUBMITTED AS C1-C3.

D RECEIVED LABELED [REDACTED] RIGHT BREAST LATERAL MARGIN IS A 2.8 X 1.8 X 0.8 CM FRAGMENT OF YELLOW FATTY TISSUE. PURPLE-BLUE COLORATION IS SEEN ON ONE SIDE OF THE SPECIMEN. THIS IS REMARKED WITH BLUE INK WITH A PERIMETER OF BLACK. THIS IS SECTIONED AND SUBMITTED AS D1 AND D2.

E RECEIVED LABELED [REDACTED] RIGHT BREAST INFERIOR MARGIN IS A 4.5 X 2.7 X 1 CM FRAGMENT OF YELLOW FATTY TISSUE. PURPLE-BLUE COLORATION IS SEEN ON APPROXIMATELY ONE-HALF OF ONE SIDE OF THE SPECIMEN. THIS SIDE IS ENTIRELY MARKED WITH BLUE INK WITH A PERIMETER OF BLACK. THIS IS SECTIONED AND SUBMITTED LABELED E1-E3.

F RECEIVED LABELED [REDACTED] RIGHT BREAST POSTERIOR MARGIN IS AN IRREGULAR FRAGMENT OF YELLOW FATTY TISSUE WITH MULTIPLE METAL CLIPS MEASURING 4.2 X 3.7 X 0.6 CM IN GREATEST DIMENSION. PURPLE-BLUE

[page 3 of 5]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req# [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

.D.

GROSS DESCRIPTION

(Continued)

COLORATION IS SEEN ON ONE SIDE OF THE SPECIMEN WHICH IS THEN REMARKED WITH BLUE INK WITH A PERIMETER OF BLACK. THIS IS SECTIONED AND SUBMITTED AS F1-F3.

G RECEIVED LABELED [REDACTED] RIGHT BREAST ANTERIOR MARGIN IS AN IRREGULAR FRAGMENT OF YELLOW FATTY TISSUE MEASURING 5.6 X 3.5 X 1.1 CM IN GREATEST DIMENSION. PURPLE-BLUE COLORATION IS SEEN ON ONE SIDE OF THE SPECIMEN WHICH ALSO DEMONSTRATES BLUE DYE WITHIN THE TISSUE. THIS SIDE IS REMARKED WITH BLUE INK WITH A PERIMETER OF BLACK. THIS IS SECTIONED AND SUBMITTED LABELED G1-G7.

H RECEIVED LABELED [REDACTED] RIGHT BREAST MEDIAL POSTERIOR MARGIN IS A 4.2 X 3.2 X 0.5 CM FRAGMENT OF YELLOW FATTY TISSUE. BLUE COLORATION IS SEEN ON ONE SIDE OF THE SPECIMEN. THIS SIDE IS REMARKED WITH BLUE INK WITH A PERIMETER OF BLACK. THIS IS SECTIONED AND SUBMITTED LABELED H1-H3.

I RECEIVED LABELED [REDACTED] RIGHT AXILLARY SENTINEL NODE HOT AND BLUE COUNT 241 IS A 5 X 3.5 X 1.5 CM FRAGMENT OF YELLOW FATTY TISSUE. EXAMINATION REVEALS 2 NODAL STRUCTURES. ONE IS 4.0 X 0.8 X 0.4 CM. THIS IS SECTIONED INTO MULTIPLE PIECES AND SUBMITTED AS I1 AND 2. THE 2ND MEASURES 0.6 X 0.4 X 0.2 CM. THIS IS SUBMITTED LABELED I3.

COMMENT: THIS CASE IS IN COMPLIANCE WITH CAP GUIDELINES OF 6-48 HOURS FORMALIN FIXATION TIME.

PATH PROCEDURES

PROCEDURES:

88307/9, IMMUNOPEROXIDAS/2, A BLK/12, B BLK/9, C BLK/3, D BLK/2, E BLK/3, F BLK/3, G BLK/7, H BLK/3, IBX X6/3

FINAL DIAGNOSIS

PART A RIGHT BREAST, PARTIAL MASTECTOMY:

1. POORLY DIFFERENTIATED MALIGNANT NEOPLASM WITH OSTEOSARCOMATOUS FEATURES WHICH MOST LIKELY REPRESENTS A METAPLASTIC CARCINOMA OF BREAST NUCLEAR GRADE 3 WITH HIGH MITOTIC INDEX WITH FOCI OF MALIGNANT OSTEOID FORMATION.

Metaplastic CA
3/3/3
3.4cm
osteoid
formation

⊖ margins
- LVI
8x0
⊖ skin

[page 4 of 5]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

M.D.

FINAL DIAGNOSIS

(Continued)

2. ADJACENT BREAST TISSUE WITH FOCI OF INTERMEDIATE TO HIGH GRADE DUCTAL CARCINOMA IN SITU OF SOLID AND CRIBRIFORM TYPE WITH FOCI OF INTRADUCTAL NECROSIS AND CALCIFICATION.
3. THE INVASIVE NEOPLASM MEASURES 34 MM IN GREATEST DIMENSION AND IS PRESENT 2 MM FROM THE POSTERIOR MARGIN AND 5 MM OR GREATER FROM ALL OTHER MARGINS.
4. THE LARGEST FOCUS OF DCIS MEASURES 10 MM IN GREATEST DIMENSION. DCIS IS PRESENT 1 MM FROM THE INFERIOR MARGIN, 2 MM FROM THE LATERAL MARGIN AND 5 MM OR GREATER FROM ALL OTHER MARGINS.
5. LYMPHATIC INVASION IS NOT IDENTIFIED.
6. BIOPSY SITE CHANGE WITH REACTIVE FIBROSIS AND FAT NECROSIS.
7. SEGMENT OF BENIGN SKIN.

adj
DCIS gr 23
solid
crib
nec Cat

PART B RIGHT BREAST, MEDIAL MARGIN REEXCISION: FIBROCYSTIC DISEASE WITH A FOCUS OF ATYPICAL DUCT HYPERPLASIA, DUCT HYPERPLASIA OF THE USUAL TYPE AND SCLEROSING ADENOSIS. A FEW CALCIFICATIONS ARE PRESENT. THE NEW INKED MARGIN IS FREE OF NEOPLASM.

FCC ADH
IDH-2
SA Cat

PART C RIGHT BREAST, SUPERIOR MARGIN REEXCISION: INTERMEDIATE GRADE DUCTAL CARCINOMA IN SITU WITH EXTENSION INTO TERMINAL LOBULES WITH FOCAL INTRADUCTAL NECROSIS. DCIS IS PRESENT 3 MM FROM THE NEW INKED MARGIN. RESIDUAL INVASIVE NEOPLASM IS NOT IDENTIFIED. THE AREA INVOLVED BY DCIS HAS A CALCULATED DIMENSION OF APPROXIMATELY 8 MM.

DCIS gr 2
lob ca
nec

PART D RIGHT BREAST, LATERAL MARGIN REEXCISION: LIPOMATOUS BREAST TISSUE WITH NO EVIDENCE OF RESIDUAL TUMOR. THE NEW INKED MARGIN IS FREE OF NEOPLASM.

⊖

PART E RIGHT BREAST, INFERIOR MARGIN REEXCISION: LOW GRADE DUCTAL CARCINOMA IN SITU OF CRIBRIFORM TYPE NUCLEAR GRADE 1 WITH LOW MITOTIC INDEX MEASURING 4 MM IN GREATEST DIMENSION. DCIS IS PRESENT 2 MM FROM THE NEW INKED MARGIN. RESIDUAL INVASIVE TUMOR IS NOT IDENTIFIED.

2mm marg
DCIS gr 1
crib

PART F RIGHT BREAST, POSTERIOR MARGIN REEXCISION: LIPOMATOUS TISSUE WITH NO EVIDENCE OF RESIDUAL NEOPLASM. THE NEW INKED MARGIN IS FREE OF NEOPLASM.

⊖

PART G RIGHT BREAST, ANTERIOR MARGIN REEXCISION: NO EVIDENCE OF RESIDUAL NEOPLASM. THE NEW INKED MARGIN IS FREE OF NEOPLASM.

⊖

[page 5 of 5]
Patient: [REDACTED]

(Continued)

Specimen:

Received:

Status:

Req#: [REDACTED]

Collected:

Sp type: SURGICAL P

Subm Dr:

FINAL DIAGNOSIS

(Continued)

PROLIFERATIVE FIBROCYSTIC DISEASE WITH NUMEROUS CALCIFICATIONS PRESENT.

FCC Cat

PART H RIGHT BREAST, MEDIAL POSTERIOR MARGIN REEXCISION: LIPOMATOUS TISSUE AND SKELETAL MUSCLE WITH NO EVIDENCE OF RESIDUAL NEOPLASM. THE NEW INKED MARGIN IS FREE OF NEOPLASM.

PART I RIGHT SENTINEL NODE, BIOPSY: LYMPH NODE (1), NEGATIVE FOR TUMOR BY STEP SECTION AND CYTOKERATIN STAIN.

0/1 SN

COMMENT

MULTIPLE BLOCKS OF THE INVASIVE NEOPLASM ARE STAINED WITH CYTOKERATIN STAIN AND DEMONSTRATE VIRTUALLY NO STAINING OF THE INVASIVE TUMOR ALTHOUGH FOCI OF ADJACENT DCIS DO DEMONSTRATE STAINING. THIS TUMOR IS MOST LIKELY A METAPLASTIC CARCINOMA OF BREAST DUE TO THE ASSOCIATION WITH DUCTAL CARCINOMA IN SITU.

Signed _____ Electronically signed by: _____

, M.D.

Pathology	Yes	No
Discrepancy		
Reviewed		
Reviewed		

10/24/12

Source: NCI Genomic Data Commons file 3dede6f4-668e-4678-b80c-5aa036180fe6 (TCGA-A2-A4S1.041580F0-700A-4A47-83A6-207ED267E844.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).